Somatic mutation profile of tumor specimen TARGET-10-PAPEZR-09A (aliquot TARGET-10-PAPEZR-09A-01D) from TARGET case TARGET-10-PAPEZR, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (665 days).
Specimen TARGET-10-PAPEZR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbd5558d-5ab8-4951-b3dd-bd0ba2a13948.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPEZR-10A (Blood Derived Normal), aliquot TARGET-10-PAPEZR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4658d93c-8ebf-42da-baba-2e608d685056

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPHA4 | c.568G>T p.A190S | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99916698; called by muse, mutect2
- KIR2DL1 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs757909487, COSV52406138; called by muse, mutect2, varscan2
- MCF2L | c.731C>T p.T244M (on ENST00000375608; = p.T212M on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.931); catalogued as rs376518005; called by muse, mutect2, varscan2
- IGKV2D-29 | chr2:89948266 del TCCTC | Missense Mutation (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel
- NKAPD1 | c.410C>G p.S137C (on ENST00000280352 / NM_001082970.2; = p.S138C on NM_018195.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/192 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2
- PPP1R37 | c.1213G>A p.G405R | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- TRAJ7 | c.2_3insGG p.D2Gfs*? | Frame Shift Ins (INS) | VAF 21/55 reads (38%) | called by mutect2, pindel, varscan2
- WSCD2 | c.1089G>T p.L363F | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- MUC2 | c.3141C>T p.A1047= | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as rs557520784; called by muse, mutect2
- TAS2R41 | c.85C>T p.L29= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs1563144115; called by muse, varscan2
